Somatic mutation profile of tumor specimen TCGA-G4-6294-01A (aliquot TCGA-G4-6294-01A-11D-1806-10) from TCGA case TCGA-G4-6294, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.0 years (27,755 days).
Specimen TCGA-G4-6294-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b1f6da-e7d4-4eb0-8fed-83ce63958181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6294-10A (Blood Derived Normal), aliquot TCGA-G4-6294-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff94da29-7fef-45ad-b73c-6c6f8acd8bfa

The open-access MAF lists 165 somatic variants for this specimen: 134 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 27, Nonsense Mutation 14, Splice Site 5, Splice Region 3, Frame Shift Del 3, Intron 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 41/116 reads (35%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 58/162 reads (36%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, varscan2
- KMT2B | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1459799356, COSV55860009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 131/152 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 54/66 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs773841241, COSV55296397; called by muse, mutect2, varscan2
- ABCB4 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV99710276; called by muse, mutect2, varscan2
- ABCC5 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99656791; called by muse, mutect2, varscan2
- ACER3 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53599032, COSV53602108; called by muse, mutect2, varscan2
- ACOXL | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1280420086, COSV61329149; called by muse, mutect2, varscan2
- ADAM33 | c.2125A>T p.S709C | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV62936381; called by muse, mutect2
- ADAMTS2 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51077696; called by muse, mutect2, varscan2
- ADGRB2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs961490668, COSV57072761; called by muse, mutect2, varscan2
- ADORA1 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV55143785; called by muse, mutect2, varscan2
- ALDH1L1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV56417944; called by muse, mutect2, varscan2
- APCS | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | catalogued as rs879661012, COSV54817191; called by muse, mutect2, varscan2
- ATP1A3 | c.1750G>T p.D584Y (on ENST00000545399 / NM_001256214.2; = p.D571Y on NM_152296.5) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100132509, COSV57490342; called by muse, mutect2, varscan2
- BIRC6 | c.9821T>C p.V3274A | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV70204088; called by muse, mutect2, varscan2
- BOD1L1 | c.7878C>G p.N2626K | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.054); catalogued as COSV50042251; called by muse, mutect2, varscan2
- CD9 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as COSV50531219; called by muse, mutect2, varscan2
- CDC42BPB | c.3456C>G p.D1152E | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150060973, COSV63474622; called by muse, mutect2, varscan2
- CDH9 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs138749280; called by muse, mutect2, varscan2
- CFH | c.2313C>A p.F771L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100809429, COSV66411071; called by muse, mutect2, varscan2
- CNTNAP4 | c.1692T>A p.C564* | Nonsense Mutation (SNP) | VAF 50/111 reads (45%) | catalogued as COSV56695534; called by muse, mutect2, varscan2
- COL11A2 | c.4480C>A p.P1494T (on ENST00000341947 / NM_080680.3; = p.P1387T on NM_080679.2) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59501071; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- COL14A1 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52862588; called by muse, mutect2, varscan2
- COL28A1 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767461836, COSV68083951; called by muse, mutect2, varscan2
- CYFIP2 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV59035359, COSV59047931; called by muse, mutect2, varscan2
- DCLK1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 169/220 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55203404; called by muse, mutect2, varscan2
- DGAT1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60048989; called by muse, mutect2, varscan2
- DISP3 | c.2709G>C p.W903C | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53834952; called by muse, mutect2, varscan2
- DNAH11 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV100178987, COSV60961767; called by muse, mutect2, varscan2
- DOCK11 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52245570; called by muse, mutect2, varscan2
- DYM | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV53990448; called by mutect2, varscan2
- EDNRA | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.416); catalogued as rs146147419; called by muse, mutect2, varscan2
- EPHA10 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs562741164, COSV57626370; called by muse, mutect2, varscan2
- FAM47C | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 141/159 reads (89%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs781997233, COSV63731372; called by muse, mutect2, varscan2
- FAM9A | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.071); catalogued as rs767408984, COSV101121339; called by muse, mutect2, varscan2
- FAT4 | c.14222A>T p.Q4741L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV58702302; called by muse, mutect2, varscan2
- FCN2 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV52478244; called by muse, mutect2, varscan2
- FGA | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV57399468; called by muse, mutect2, varscan2
- GAL3ST4 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as rs745563991, COSV57585738; called by muse, mutect2, varscan2
- GATB | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1257238597, COSV99858972; called by muse, mutect2
- GLI3 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 130/214 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV67893508; called by muse, mutect2, varscan2
- GPATCH8 | c.4031C>A p.P1344Q | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100132370, COSV59197290; called by muse, mutect2, varscan2
- GPS2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 183/226 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59752488; called by muse, mutect2, varscan2
- GRID2 | c.172T>A p.L58I | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56248058; called by muse, mutect2, varscan2
- GRM2 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs201981098, COSV99622763; called by muse, mutect2, varscan2
- GRPEL2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV61388086; called by muse, mutect2, varscan2
- GTF3C4 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64645889; called by muse, mutect2, varscan2
- HELT | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1413555688, COSV58819766; called by muse, mutect2, varscan2
- IGKV1-5 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 164/198 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs567604618; called by muse, mutect2
- ITGA8 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs369955410, COSV65227857; called by muse, mutect2, varscan2
- JPH3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298741562, COSV52472482; called by muse, mutect2, varscan2
- KANK2 | c.1418G>T p.G473V (on ENST00000586659 / NM_001379562.1; = p.G481V on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV62009081, COSV62009421; called by muse, mutect2, varscan2
- KCNH8 | c.2424C>A p.D808E | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV60473017; called by muse, mutect2, varscan2
- KCNQ2 | c.1235A>T p.E412V (on ENST00000359125 / NM_172107.4; = p.E402V on NM_004518.6) | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100610081; called by muse, mutect2, varscan2
- KCTD12 | c.905T>A p.F302Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV58524978; called by muse, mutect2, varscan2
- KLHL1 | c.681-2A>T p.X227_splice | Splice Site (SNP) | VAF 11/202 reads (5%) | catalogued as COSV100917167, COSV64785555; called by muse, mutect2
- KLRG1 | c.531A>C p.E177D | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV56944681; called by muse, mutect2, varscan2
- KRTAP15-1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 59/122 reads (48%) | catalogued as COSV61877014, COSV61877885; called by muse, mutect2, varscan2
- LGSN | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs761631352, COSV101040495; called by muse, mutect2, varscan2
- LINGO1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs373336312; called by muse, mutect2, varscan2
- LRP3 | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.326); catalogued as COSV53506607; called by muse, mutect2, varscan2
- LRRIQ3 | c.753A>C p.R251S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63041448, COSV63048416; called by muse, mutect2, varscan2
- MAGEC3 | c.541A>T p.T181S | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1184651733, COSV53580881; called by muse, mutect2, varscan2
- MAGED1 | c.1997T>A p.F666Y | Missense Mutation (SNP) | VAF 137/146 reads (94%) | SIFT tolerated, low confidence (0.78); PolyPhen possibly damaging (0.899); catalogued as COSV58516422; called by muse, mutect2, varscan2
- MAN1A1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs774209358, COSV63782664; called by muse, mutect2, varscan2
- MAN2B2 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs200380914, COSV53455895; called by muse, mutect2, varscan2
- MAP10 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV69364597; called by muse, mutect2, varscan2
- MEGF8 | c.7005G>C p.E2335D (on ENST00000251268 / NM_001271938.2; = p.E2268D on NM_001410.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV52097217; called by muse, mutect2, varscan2
- MTMR9 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs751005436, COSV55314658; called by muse, mutect2, varscan2
- MUC4 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 378/634 reads (60%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.788); catalogued as rs772115464, COSV62129749; called by muse, mutect2, varscan2
- MYCBP2 | c.5685T>A p.D1895E (on ENST00000357337; = p.D1933E on NM_015057.5) | Missense Mutation (SNP) | VAF 81/610 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV62034080; called by muse, mutect2, varscan2
- MYH14 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761967521, COSV51828157; called by muse, mutect2, varscan2
- MYH2 | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 150/178 reads (84%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs886043621, COSV55437079, COSV55445634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIBAN3 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.474); catalogued as COSV99962118; called by muse, mutect2, varscan2
- OR10J1 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV71129410; called by muse, varscan2
- OR2W1 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV65851829; called by muse, mutect2, varscan2
- OTP | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60569687; called by muse, mutect2, varscan2
- OXSR1 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 70/204 reads (34%) | catalogued as COSV100309324; called by muse, mutect2, varscan2
- PAX4 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1370643668, COSV58387446; called by muse, mutect2, varscan2
- PCDH18 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV61271322; called by muse, mutect2, varscan2
- PCDHB2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.066); catalogued as rs1380629175, COSV99165001; called by muse, mutect2, varscan2
- PDE3A | c.845A>T p.D282V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs753232121, COSV62980255; called by muse, mutect2, varscan2
- PDSS2 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100941726; called by muse, mutect2, varscan2
- PDYN | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 53/244 reads (22%) | catalogued as COSV54103070; called by muse, mutect2, varscan2
- PIK3C2G | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 98/261 reads (38%) | catalogued as COSV56826608; called by muse, mutect2, varscan2
- PLEKHA2 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66243320; called by muse, mutect2, varscan2
- PLEKHA5 | c.1812G>C p.Q604H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV54709980; called by muse, mutect2, varscan2
- PLEKHM1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 101/128 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760295037, COSV69598463; called by muse, mutect2, varscan2
- PLIN4 | c.98C>T p.A33V (on ENST00000301286; = p.A48V on NM_001367868.2) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs774259750, COSV56696713; called by muse, mutect2, varscan2
- POLR2G | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV57135589; called by muse, mutect2, varscan2
- POTEA | c.1159C>A p.P387T (on ENST00000519951 / NM_001005365.2; = p.P341T on NM_001002920.1) | Missense Mutation (SNP) | VAF 183/452 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as rs1474244351; called by muse, mutect2, varscan2
- PRF1 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV64615686; called by muse, mutect2, varscan2
- PTPN13 | c.4138A>T p.I1380L (on ENST00000411767 / NM_080683.3; = p.I1361L on NM_006264.3) | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as rs931955706, COSV57414644; called by muse, mutect2, varscan2
- PWWP3B | c.1099T>A p.S367T | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.442); catalogued as COSV61801230; called by muse, mutect2, varscan2
- PXDN | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.951); catalogued as COSV99413231; called by muse, mutect2, varscan2
- RAC2 | c.289-2A>G p.X97_splice | Splice Site (SNP) | VAF 120/143 reads (84%) | catalogued as COSV50775111; called by muse, mutect2, varscan2
- SFMBT2 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV62814667; called by muse, mutect2, varscan2
- SHB | c.1519A>T p.R507W | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100891707; called by muse, mutect2, varscan2
- SHPRH | c.3783-1G>C p.X1261_splice (on ENST00000275233 / NM_001042683.3; = p.X1265_splice on NM_173082.3) | Splice Site (SNP) | VAF 48/138 reads (35%) | catalogued as COSV51615659, COSV51617030; called by muse, mutect2, varscan2
- SI | c.2762T>G p.L921R | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52289967; called by muse, mutect2, varscan2
- SLC27A6 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs373236456; called by muse, mutect2, varscan2
- SMCR8 | c.2462T>A p.L821H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as COSV68811356; called by muse, mutect2, varscan2
- SPEF2 | c.5380-2A>C p.X1794_splice | Splice Site (SNP) | VAF 111/297 reads (37%) | catalogued as COSV57431399; called by muse, mutect2, varscan2
- SPTBN5 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs531720902, COSV58026172; called by muse, mutect2, varscan2
- SRI | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56001309; called by muse, mutect2, varscan2
- SRMS | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV53918064; called by muse, mutect2, varscan2
- STK31 | c.2277C>T p.G759= | Splice Region (SNP) | VAF 31/100 reads (31%) | catalogued as COSV63455240, COSV63455288; called by muse, mutect2, varscan2
- STK32A | c.517A>G p.R173G | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100096976; called by muse, mutect2, varscan2
- TBR1 | c.2025C>G p.Y675* | Nonsense Mutation (SNP) | VAF 60/140 reads (43%) | catalogued as COSV67418892; called by muse, mutect2, varscan2
- TENM3 | c.5716C>T p.R1906* | Nonsense Mutation (SNP) | VAF 73/149 reads (49%) | catalogued as COSV69308742; called by muse, mutect2, varscan2
- TMEM132B | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 140/168 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745625674, COSV54765220; called by muse, mutect2, varscan2
- TMEM132D | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs200646338, COSV101398364, COSV70598520; called by muse, mutect2, varscan2
- TMEM201 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1173208406, COSV61050990; called by muse, mutect2, varscan2
- TNNC2 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV65332669; called by muse, mutect2, varscan2
- TNR | c.1724G>C p.S575T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.076); catalogued as COSV54906467, COSV54918617; called by muse, mutect2, varscan2
- TRPC4 | c.1094A>T p.K365M | Missense Mutation (SNP) | VAF 67/417 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59006610, COSV59012215; called by muse, mutect2, varscan2
- TTK | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1162243458, COSV57886007; called by muse, mutect2, varscan2
- TTN | c.50314G>C p.E16772Q (on ENST00000591111; = p.E9348Q on NM_003319.4) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | PolyPhen possibly damaging (0.603); catalogued as COSV59918711, COSV60264547; called by muse, mutect2, varscan2
- TXNDC2 | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs1473272517, COSV100046051; called by muse, varscan2
- VCPIP1 | c.1640G>C p.R547P | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60049637; called by muse, mutect2, varscan2
- VCX | c.105T>A p.T35= | Splice Region (SNP) | VAF 81/673 reads (12%) | catalogued as COSV58233133; called by muse, mutect2, varscan2
- VCX2 | c.105T>A p.T35= | Splice Region (SNP) | VAF 59/451 reads (13%) | catalogued as COSV100400026; called by muse, varscan2
- VPS37A | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as rs774257401, COSV61353212; called by muse, mutect2, varscan2
- ZFHX3 | c.10134G>T p.Q3378H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV51730513; called by muse, mutect2, varscan2
- ZNF704 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV59927293; called by muse, mutect2, varscan2
- ZNF77 | c.892T>A p.C298S | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58822501; called by muse, mutect2, varscan2
- CTTNBP2 | c.1966del p.V657Sfs*12 | Frame Shift Del (DEL) | VAF 38/127 reads (30%) | called by mutect2, pindel, varscan2
- MBD6 | c.2633_2670del p.R878Pfs*26 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by mutect2, pindel
- NRF1 | c.1348+5_1348+26del p.X450_splice | Splice Site (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- SHLD2 | c.939del p.F313Lfs*15 | Frame Shift Del (DEL) | VAF 71/279 reads (25%) | called by mutect2, pindel, varscan2
- ATP7B | c.4107A>T p.S1369= | Silent (SNP) | VAF 47/360 reads (13%) | catalogued as COSV54442162; called by muse, mutect2, varscan2
- C5 | c.906T>C p.D302= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV56331115; called by muse, mutect2, varscan2
- CAMTA1 | c.4479G>A p.A1493= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs775434446, COSV100348764; called by muse, mutect2, varscan2
- CNNM1 | c.936C>T p.T312= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV63203103; called by muse, mutect2, varscan2
- DPPA5 | c.309C>T p.A103= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV64875544; called by muse, mutect2, varscan2
- FAM171A1 | c.2520G>A p.A840= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs764070086, COSV65314502; called by muse, mutect2, varscan2
- FRY | c.6594G>A p.T2198= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as rs752351313, COSV66564346; called by muse, mutect2, varscan2
- GPC6 | c.816C>T p.N272= | Silent (SNP) | VAF 111/142 reads (78%) | catalogued as rs113591716, COSV100988543; called by muse, mutect2, varscan2
- HIVEP3 | c.5766G>A p.E1922= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV56021243; called by muse, mutect2, varscan2
- KRTAP19-1 | c.51C>A p.G17= | Silent (SNP) | VAF 106/296 reads (36%) | catalogued as COSV66861111; called by muse, mutect2, varscan2
- LRIG3 | c.1365C>A p.L455= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100292472, COSV57868275; called by muse, mutect2, varscan2
- MMP26 | c.48C>T p.F16= | Silent (SNP) | VAF 91/221 reads (41%) | catalogued as rs757679480, COSV56171254; called by muse, mutect2, varscan2
- OR5M10 | c.777C>T p.Y259= | Silent (SNP) | VAF 136/331 reads (41%) | catalogued as rs199665621; called by muse, mutect2, varscan2
- OTOF | c.825G>A p.V275= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV55514671; called by muse, mutect2, varscan2
- PAX1 | c.432C>T p.H144= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV68273131; called by muse, mutect2
- PCDHB16 | c.1899C>T p.R633= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV53359682, COSV53371657; called by muse, mutect2, varscan2
- PHYHD1 | c.552C>T p.N184= (on ENST00000372592 / NM_001100876.2; = p.T177M on NM_174933.4) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs755661083, COSV58282162; called by muse, mutect2, varscan2
- POU4F2 | c.243C>T p.G81= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs752990850, COSV55586209; called by muse, mutect2, varscan2
- SLC41A1 | c.1242C>A p.L414= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV65651011; called by muse, mutect2, varscan2
- TDGF1 | c.75G>A p.L25= | Silent (SNP) | VAF 104/276 reads (38%) | catalogued as COSV56126205; called by muse, mutect2, varscan2
- TIE1 | c.1296C>T p.G432= | Silent (SNP) | VAF 72/173 reads (42%) | catalogued as rs754628532, COSV65250937; called by muse, mutect2, varscan2
- TPTE | c.738T>A p.I246= (on ENST00000618007 / NM_199261.4; = p.I228= on NM_199259.4) | Silent (SNP) | VAF 118/553 reads (21%) | catalogued as rs761798725; called by muse, mutect2, varscan2
- TTN | c.30996G>A p.K10332= (on ENST00000591111; = p.K9405= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as rs1357684788, COSV59890491, COSV60264561; called by muse, mutect2, varscan2
- TTN | c.15675T>A p.P5225= (on ENST00000591111; = p.P4298= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV100609789; called by muse, mutect2, varscan2
- VRTN | c.1095C>T p.P365= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs199640090, COSV56443032; called by muse, mutect2, varscan2
- VXN | c.145C>T p.L49= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV59686619; called by muse, mutect2, varscan2
- ZFHX4 | c.4050G>A p.P1350= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as rs749725605, COSV50737398, COSV99266767; called by muse, mutect2, varscan2
- AC092718.9 | n.11A>T | RNA (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- AC244258.1 | n.344C>G | RNA (SNP) | VAF 51/180 reads (28%) | called by muse, mutect2, varscan2
- SARDH | c.1020+246C>T | Intron (SNP) | VAF 23/51 reads (45%) | catalogued as rs772869184, COSV100897930; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1922G>C | Intron (SNP) | VAF 148/406 reads (36%) | catalogued as COSV62466114, COSV62468544; called by muse, mutect2, varscan2
